Surgical pathology report (de-identified scan), TCGA case TCGA-32-2494, project TCGA-GBM (Glioblastoma Multiforme), tissue source site St. Joseph's Hospital (AZ), specimen TCGA-32-2494-01A (Primary Tumor).

NEUROPATHOLOGY REPORT

SPECIMEN SOURCE:

1. Temporal lobe tumor
2. Temporal lobe tumor
3. Anterior tumor margin

TCGA-32-2494

CLINICAL DIAGNOSIS:

Seizures

GROSS DESCRIPTION:

1. Received fresh for frozen section are three fragments of tan-pink soft tissue aggregating to 0.5 x 0.3 x 0.1 cm. A smear is performed and the specimen is entirely frozen on one chuck.

FROZEN SECTION DIAGNOSIS:

GLIOBLASTOMA.

2. Received in formalin labeled with the patient's name and "temporal lobe tumor" are several fragments of pink-tan to white soft tissue aggregating to 1.9 x 0.7 x 0.3 cm. The specimen is entirely submitted in one cassette.

3. Received in formalin labeled with the patient's name and "anterior tumor margin" are three fragments of tan-pink to red-black soft tissue aggregating to 1.0 x 0.6 x 0.3 cm. The specimen is entirely submitted in one cassette.

One half of a portion of a specimen is sent to

MICROSCOPIC DESCRIPTION:

1, 2. Sections demonstrate markedly hypercellular glial neoplasm, the cells of which resemble atypical fibrillary astrocytes. The tumor has both cellular areas and also infiltrates the surrounding parenchyma. Microvascular proliferation is prominent. There are foci of tumor necrosis including those with pseudopalisading. Scattered mitotic figures are seen.

3. The sections designated interior tumor margin actually demonstrates greater cellularity than seen in the first two specimens. Otherwise the features are similar.

DIAGNOSIS:

(PROVISIONAL)

- 1, 2. TEMPORAL LOBE TUMOR, BIOPSY AND RESECTION:
GLIOBLASTOMA (WHO GRADE IV).

3. ANTERIOR TUMOR MARGIN:
POSITIVE FOR CELLULAR GLIOBLASTOMA.

ADDENDUM NEUROPATHOLOGY REPORT

ADDENDUM DISCUSSION:

Approximately 50-75% of the neoplastic cells demonstrate immunoreactivity for MGMT. The majority of the histologic sections include cellular tumor.

ADDENDUM DIAGNOSIS:

- 1, 2. TEMPORAL LOBE TUMOR, BIOPSY AND RESECTION:
GLIOBLASTOMA (WHO GRADE IV)
- 50-75% MGMT IMMUNOREACTIVITY.

Source: NCI Genomic Data Commons file 11df5aef-d731-438d-b7e4-82ba3a3543d2 (TCGA-32-2494.9EC0CA6E-FF5A-4D34-A2E9-3889F4DD6E46.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).